Somatic mutation profile of tumor specimen BA2933D (aliquot aq-BA2933D) from BEATAML1.0 case 2338, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.5 years (22,455 days).
Specimen BA2933D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0a2cb99-bfeb-450e-93e6-49eb6caea42f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2495D (Solid Tissue Normal), aliquot aq-BA2495D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41b29236-51f0-4ace-986d-011ac3661649

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 144/322 reads (45%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMC1A | c.2369G>A p.R790Q | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs797045993, CM071099, COSV59127614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY6 | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as rs756690261; called by muse, mutect2, varscan2
- C2CD4C | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as rs893101476; called by muse, mutect2
- GPRIN2 | c.443G>A p.S148N | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.361); catalogued as rs1555019588; called by mutect2, varscan2
- ITGAE | c.503A>G p.E168G | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1313192748; called by muse, mutect2, varscan2
- KCND3 | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1332646922, COSV56175522; called by muse, mutect2, varscan2
- MAPK13 | c.1072C>T p.R358W | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs759807867, COSV99274972; called by muse, mutect2, varscan2
- SLC35G3 | c.302G>A p.R101Q | Missense Mutation (SNP) | VAF 124/293 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs147490548; called by muse, mutect2, varscan2
- ACAN | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 92/222 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- ANGPTL1 | c.516C>G p.Y172* | Nonsense Mutation (SNP) | VAF 92/186 reads (49%) | called by muse, mutect2, varscan2
- DCUN1D3 | c.489T>G p.C163W | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- GLDN | c.484C>A p.P162T | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PPP1R12A | c.2723C>G p.S908C | Missense Mutation (SNP) | VAF 76/202 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- IQCA1 | c.1617C>G p.P539= | Silent (SNP) | VAF 44/100 reads (44%) | called by muse, mutect2, varscan2
- RYR1 | c.5085C>T p.H1695= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as rs562668984, COSV62104357; called by muse, varscan2
- SH2B1 | c.1898-190C>T | Intron (SNP) | VAF 14/45 reads (31%) | catalogued as rs370302573; called by muse, varscan2
